Gene-level copy-number profile of tumor specimen TCGA-AA-3521-01A from TCGA case TCGA-AA-3521, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage II; Age at diagnosis: 87.1 years (31,805 days).
Specimen TCGA-AA-3521-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.d3d40b14-9a76-497d-9c71-e31b7cc3cdb9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3521-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5a35568e-6ada-4d85-9f47-3cf31950705e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 54; copy number 2: 8,963; copy number 3: 28,302; copy number 4: 11,071; copy number 5: 8,715; copy number 6: 300; copy number 9: 949; copy number 10: 74; copy number 11: 1,391.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3521-01A-01D-1549-01): tumor purity 0.7, ploidy 3.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,414 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 11 (broad region; genes not listed).
- chr20:22,960,534–64,313,132, 1,023 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 54. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
